Gene-level copy-number profile of tumor specimen ALCH-ABC2-TTP1-A from ALCHEMIST case ALCH-ABC2, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 63.7 years (23,249 days).
Specimen ALCH-ABC2-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 256db8f5-9dcb-455f-a4b6-db8c8cf13e6d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ABC2-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,761 have no estimate.
https://portal.gdc.cancer.gov/files/d3ad4d0e-6b59-4ae9-a911-78a9a2a2a840

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 129; copy number 1: 3,299; copy number 2: 55,371; copy number 3: 34; copy number 4: 14; copy number 5: 3; copy number 6: 2; copy number 7: 1; copy number 8: 7; copy number 12: 1; copy number 15: 1.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,234,174–89,234,912, 1 gene (within-gene range 0–2): IGKV2-29.
- chr7:1,542,235–1,560,821, 1 gene (within-gene range 0–2): TMEM184A.
- chr9:128,455,186–128,501,292, 2 genes: ODF2, ODF2-AS1.
- chr14:18,333,726–18,343,144, 2 genes: CR383658.1, RNU6-458P.
- chr16:88,186,605–88,195,217, 2 genes: LINC02182, AC134312.6.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 15 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:89,295–133,723, 1 gene, copy number 8 (within-gene range 2–8): AL627309.1.
- chr1:131,025–157,887, 5 genes, copy number 8: CICP27, AL627309.6, AL627309.7, AL627309.2, RNU6-1100P.
- chr1:587,629–594,768, 1 gene, copy number 6 (within-gene range 3–6): AC114498.1.
- chr8:7,170,550–7,200,857, 3 genes, copy number 7–15: SNRPCP15, RPS3AP33, AF228730.1.
- chr8:7,295,014–7,298,024, 1 gene, copy number 5: FAM90A20P.
- chr10:95,141,925–95,168,425, 1 gene, copy number 6: AL157834.4.
- chr22:18,178,038–18,345,899, 2 genes, copy number 5: FAM230D, GGTLC5P.
- chr22:18,527,802–18,530,573, 1 gene, copy number 12: TMEM191B.

Autosomal genes at a single copy (total copy number 1): 625. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
